Gene-level copy-number profile of tumor specimen C3N-03080-02 from CPTAC case C3N-03080, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 68.0 years (24,834 days).
Specimen C3N-03080-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 150c72b4-2110-4b6b-ac00-b90abd90deaa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03080-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/1f97ca7e-a1f5-434e-8329-09f5f53f6a51

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 6,633; copy number 2: 39,738; copy number 3: 8,985; copy number 4: 3,423; copy number 5: 6; copy number 6: 31; copy number 7: 3; copy number 8: 4; copy number 14: 9.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–23,438,700, 64 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 53 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 1 gene, copy number 5 (within-gene range 3–5): AL627309.1.
- chr1:131,025–522,928, 14 genes, copy number 5–14: CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr5:169,552,449–171,457,626, 35 genes, copy number 6–8: RNU6-477P, SPDL1, DOCK2, AC008680.1, INSYN2B, MIR378E, FOXI1, KRT18P41, LINC01187, C5orf58, LCP2, LINC01366, AC034199.1, KCNIP1, KCNMB1, KCNIP1-OT1, AC008619.1, KCNIP1-AS1, AC008514.1, GABRP, RANBP17, RN7SL623P, AC008514.2, USP12P1, AC091980.2, TLX3, AC091980.1, RN7SL339P, RPSAP71, SNORA70J, RPL10P8, MIR3912, NPM1, FGF18, AC093246.1.
- chr12:6,375,045–6,410,013, 3 genes, copy number 7 (within-gene range 4–7): LTBR, AC005840.2, AC005840.1.

Autosomal genes at a single copy (total copy number 1): 6,131. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
